TCGA case TCGA-26-A7UX — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: University of Florida. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5f9baf9b-6d2d-495a-83a1-77f7e4cb9ccd

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 47.5 years (17,365 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 23 days; Days to treatment end: 65 days; Treatment dose: 60 Gy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 35 days; Days to treatment end: 235 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 511 days (1.4 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 511 days (1.4 years); Treatment outcome: Treatment Ongoing.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 48.7 years (17,772 days); Days to diagnosis: 407 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 419 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 260 days; Disease response: With Tumor.
- Day 407 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 407 days (1.1 years).
- Days to follow up: 588 days (1.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-26-A7UX-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 90 mg.
  Slide TCGA-26-A7UX-01B-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-26-A7UX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-26-A7UX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Stable Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2: Treatment best response: Stable Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Avastin; Treatment best response: Stable Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Stable Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 588 days; disease-specific survival: no event (censored), 588 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 407 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-26-A7UX-01B-11D-A390-01): tumor purity 0.97, ploidy 1.97, whole-genome doublings 0.
